Gene-level copy-number profile of tumor specimen C3N-03012-01 from CPTAC case C3N-03012, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,252 days).
Specimen C3N-03012-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 01d247d3-f6eb-488d-83c2-0011c6e39cb0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03012-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/52a98feb-ee49-4872-8e80-cd9dc6670d8d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 557; copy number 1: 3,085; copy number 2: 20,845; copy number 3: 21,992; copy number 4: 10,064; copy number 5: 786; copy number 6: 234; copy number 7: 104; copy number 8: 136; copy number 9: 236; copy number 10: 23; copy number 11: 119; copy number 12: 146; copy number 13: 31; copy number 14: 150; copy number 15: 113; copy number 16: 19; copy number 17: 115; copy number 18: 92; copy number 19: 10; copy number 21: 2; copy number 22: 9; copy number 37: 27; copy number 40: 8.

Homozygous deletions (total copy number 0; autosomes only): 130 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:8,059,572–8,244,865, 10 genes: AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1, FAM86B3P, ALG1L13P.
- chr9:12,287,320–12,710,285, 3 genes: JKAMPP1, RNU2-47P, TYRP1.
- chr9:20,658,309–28,888,955, 112 genes (within-gene range 0–3) (broad region; genes not listed).
- chr17:18,450,244–18,475,920, 4 genes: KRT16P4, AL353997.1, AL353997.4, TNPO1P2.
- chr17:18,497,095–18,506,313, 1 gene: NOS2P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,340 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:233,904,104–234,324,511, 2 genes, copy number 13 (within-gene range 6–13): AL713868.1, SLC35F3.
- chr1:234,212,606–238,779,200, 101 genes, copy number 7–13 (broad region; genes not listed).
- chr2:200,488,958–200,677,064, 3 genes, copy number 9 (within-gene range 2–9): KCTD18, SGO2, AOX1.
- chr7:52,891,837–56,955,864, 101 genes, copy number 16–40 (broad region; genes not listed).
- chr7:57,060,590–57,837,046, 54 genes, copy number 17: PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr7:63,556,598–63,636,617, 4 genes, copy number 7: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1.
- chr7:83,663,419–85,636,344, 14 genes, copy number 10–15: RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr7:89,754,620–106,315,743, 402 genes, copy number 9–18 (broad region; genes not listed).
- chr8:32,911,493–33,473,146, 10 genes, copy number 10: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2.
- chr8:36,121,398–36,309,690, 6 genes, copy number 7: AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P.
- chr10:31,318,495–31,529,814, 1 gene, copy number 7 (within-gene range 4–7): ZEB1.
- chr10:31,362,799–31,628,599, 3 genes, copy number 7: AL117340.1, AL161935.1, AL161935.2.
- chr10:36,432,882–36,626,138, 6 genes, copy number 7: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.
- chr10:38,783,004–38,783,108, 1 gene, copy number 8: AL590623.1.
- chr11:4,179,675–4,596,574, 21 genes, copy number 9: LINC02749, RDXP1, SSU72P5, SSU72P2, SSU72P6, SSU72P4, SSU72P3, SSU72P7, OR52B4, OR52B3P, TRIM21, OR52K3P, OR51R1P, OR52P2P, OR52K2, OR52K1, OR52M2P, OR52M1, C11orf40, OR52I2, OR52I1.
- chr11:68,754,620–71,252,577, 61 genes, copy number 7–16 (broad region; genes not listed).
- chr14:93,718,298–94,727,175, 31 genes, copy number 7: PRIMA1, AL132642.2, FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506, CCDC197, OTUB2, DDX24, IFI27L1, IFI27, IFI27L2, PPP4R4, SERPINA10, SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, SERPINA4, SERPINA5, AL049839.2, AL049839.3, SERPINA3, ADIPOR1P2, SERPINA13P, AL049839.1, RPSAP4.
- chr14:95,876,392–97,158,736, 29 genes, copy number 7–21: TUNAR, AL137190.1, C14orf132, BDKRB2, AL355102.2, AL355102.1, CKS1BP1, AL355102.5, BDKRB1, AL355102.4, AL355102.3, ATG2B, GSKIP, RNU2-33P, AK7, PEBP1P1, RPL23AP10, AL163051.1, PAPOLA, AL137786.1, RN7SKP108, LINC02299, AL137786.3, VRK1, LINC00618, AL049833.3, AL049833.2, AL049833.1, LINC02304.
- chr14:104,924,713–106,481,706, 163 genes, copy number 9–15 (broad region; genes not listed).
- chr20:5,750,393–25,298,012, 327 genes, copy number 8–22 (within-gene range 6–85) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,235. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
